Surgical pathology report (de-identified scan), TCGA case TCGA-CD-A4MH, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-A4MH-01A (Primary Tumor).

[page 1 of 5]
Fax:

Clinical Case Report

(For Collection of Cancerous Tissue)

100-1-3

Adenocarcinoma, diffuse type
8145/3

Sites: Stomach, antrum c16.3

fw
10/3/02

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	VIETNAMESE	
☐ Male ☒ Female	46 kg	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
			10/6	

HISTORY OF PRESENT ILLNESS
Chief Complaints: Abdominal pain, black & tarry stool
Symptoms: weight loss
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☒ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☒ Post-menopausal	Date of First Menses	# of Pregnancies
	Date of Last Menses	# of Live Births
	Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____	
☐ Hormone Replacement Therapy: _____		

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers: _____					

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy	A tumour was found at the pylorus.	
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Location of Suspected Involved Lymph Nodes		Location of Suspected Distant Metastasis
Clinical Staging		Date of Diagnosis
T3 N0 M0 Stage: II		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Extended gastrectomy			
Primary Tumor			
Organ	Detailed Location	Size	
Stomach tumor	Antrum	2 x 1.5 x 1 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T3 N0 M0 Stage: II			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by: _____

_____ Date

Time: _____

Preserved by: _____

_____ Date:

Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach Tumor	2 x 1.5 x 1 cm	Antrum	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N0 M0 Stage: II			
Notes:			

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		STRUCTURAL PATTERN	
	+ -		+ -
Diffuse		Streaming	
Mosaic	X	Storiform	
Necrosis	X	Fibrosis	
Lymphocytic Infiltration	X	Palisading	
Vascular Invasion		Cystic Degeneration	
Clusterized	X	Bleeding	
Alveolar Formation		Myxoid Change	
Indian File		Psamomma/Calcification	

2. Cellular features:

Squamous	+ -	Adenomatous	+ -	Sarcomatous	+ -	Lymphomatous	+ -
Squamoid Cell		Glandular cell	X	Round Cell		Large Cell	
Spindle Cell		Cell Stratification	X	Fibroblast		Small Cell	
Keratin		Secretion	X	Osteoblast		RS Cell/RS Like	
Desmosome		Intracyt. Vacuole	X	Lipoblast		Inflam. Cell	
Pearl		Gland formation	X	Myoblast		Plasma Cell	

Otherwise Specified:

D1 50%, D2 50%, D3 60%, D4 60%, Necrosis 2%

2. Cellular Differentiation:

Well	Moderately	Poor
	X	

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			X	
Hyperchromatism			X	
Nucleolar Prominent			X	
Multinucleated Giant Cell			X	
Mitotic Activity			X	
Nuclear Grade			X	

Histological Diagnosis:

Adenocarcinoma NOS, G-2

Comments:

M, M, Fibro-fatty tissue

Date

Director, Research Pathology

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR.)

PATHOLOGIST STAFF FOR RESEARCH USE ONLY.

Source: NCI Genomic Data Commons file cadf9c4c-d2db-43cf-9dc1-f206486a8bab (TCGA-CD-A4MH.ED149C8B-1BBB-404B-A4A1-3A0A51EE301A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).